Surgical pathology report (de-identified scan), TCGA case TCGA-XQ-A8TA, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site University of Sao Paulo, specimen TCGA-XQ-A8TA-01A (Primary Tumor).

ICD-O-3
Adenocarcinoma NOS
8140/3
Site: Prostate NOS
C61.9
4/29/14

Nature of material: Prostate

Received on:

ANATOMOPATHOLOGIC RESULT

MACROSCOPY

Multiple irregular fragments of elastic and brownish tissue, which together measure 9.0 x 6.8 x 2.0 cm.

MICROSCOPY

Description dispensable.

DIAGNOSTIC

Product of transurethral resection of the prostate:

- Prostatic usual acinar adenocarcinoma, Gleason 10 (5 + 5).

PARTICIPANTS OF APPRAISAL REPORT

ISSUER

Case is (title):		

Source: NCI Genomic Data Commons file 1c3ece74-d07f-4fcd-bf7d-fdc0f5784f36 (TCGA-XQ-A8TA.8AF39C5E-73E3-40EA-B328-98892AE85971.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).